CCDI case PBCEAH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ef678279-64e7-497b-9285-225a4da5ec60

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.5 years (1,291 days).

Biospecimens (2 samples)
- Sample 0DPL7Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPL7U: Tissue type: Tumor; Specimen type: Solid Tissue.
